Somatic mutation profile of tumor specimen MP2PRT-PAPZGI-TMP1-A (aliquot MP2PRT-PAPZGI-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPZGI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.2 years (4,449 days).
Specimen MP2PRT-PAPZGI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd57c928-fa8d-4689-9210-1d665d2a8c58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZGI-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZGI-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cd7aacb-a943-40ca-883f-f4f50088b64d

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 41/333 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CASP12 | c.40A>G p.M14V | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs905884810; called by muse, mutect2, varscan2
- CELSR3 | c.7325C>T p.P2442L | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758171925; called by muse, mutect2, varscan2
- MYH2 | c.5554C>T p.R1852* | Nonsense Mutation (SNP) | VAF 36/229 reads (16%) | catalogued as rs756571003; called by muse, mutect2, varscan2
- PNPLA7 | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 86/601 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150851825; called by muse, mutect2, varscan2
- SASH1 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.276); catalogued as COSV100820949; called by muse, mutect2, varscan2
- CRYBG3 | c.2235_2244del p.P746Kfs*7 | Frame Shift Del (DEL) | VAF 32/248 reads (13%) | called by mutect2, varscan2
- ETV6 | c.1199A>G p.H400R | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRK | c.4552A>G p.K1518E | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, varscan2
- TBC1D32 | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 28/188 reads (15%) | called by muse, varscan2
- CYSLTR2 | c.222C>T p.N74= | Silent (SNP) | VAF 52/278 reads (19%) | catalogued as rs376375520; called by muse, mutect2, varscan2
- GOSR1 | c.18C>T p.S6= | Silent (SNP) | VAF 57/462 reads (12%) | catalogued as rs1283542231; called by muse, mutect2, varscan2
- LRRIQ1 | c.4065T>C p.T1355= | Silent (SNP) | VAF 41/341 reads (12%) | catalogued as COSV101280620; called by muse, mutect2, varscan2
- RPL39L | c.18T>G p.T6= | Silent (SNP) | VAF 69/148 reads (47%) | called by muse, mutect2, varscan2
